Somatic mutation profile of tumor specimen TCGA-09-2050-01A (aliquot TCGA-09-2050-01A-01W-0799-08) from TCGA case TCGA-09-2050, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.7 years (23,987 days).
Specimen TCGA-09-2050-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 206f0dd5-a1a6-41ce-8f60-cfb8ebd1b0a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2050-10A (Blood Derived Normal), aliquot TCGA-09-2050-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3903bde-44cf-4a0d-b7cb-d4b3094957e8

The open-access MAF lists 127 somatic variants for this specimen: 93 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 28, Nonsense Mutation 8, Frame Shift Del 8, Splice Site 6, Intron 3, In Frame Del 2, Splice Region 1, 5'UTR 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.5645C>A p.S1882* | Nonsense Mutation (SNP) | VAF 54/56 reads (96%) | catalogued as rs80358785, CM056302, CM980241, COSV101203821, COSV66450717; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 148/164 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934577, CD941800, CM1411657, CM941332, COSV52682484, COSV52703253, COSV52757928; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB10 | c.1660G>C p.D554H | Missense Mutation (SNP) | VAF 261/512 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60621160; called by muse, mutect2, varscan2
- AMPH | c.591-1G>A p.X197_splice | Splice Site (SNP) | VAF 78/168 reads (46%) | catalogued as COSV57749586; called by muse, mutect2, varscan2
- ANKS1A | c.2994+1G>C p.X998_splice | Splice Site (SNP) | VAF 46/157 reads (29%) | catalogued as COSV64462453; called by muse, mutect2, varscan2
- ARFGEF3 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 161/348 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52463716; called by muse, mutect2, varscan2
- ASB18 | c.257A>C p.N86T | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV58235028; called by muse, mutect2, varscan2
- BPIFB2 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV50067537, COSV50069564; called by muse, mutect2
- BST2 | c.330A>C p.Q110H | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as COSV53089351; called by muse, mutect2, varscan2
- C10orf62 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 104/174 reads (60%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.015); catalogued as rs1046645098, COSV101035270; called by muse, varscan2
- CARMIL3 | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV57727486; called by muse, mutect2, varscan2
- CCR3 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 134/142 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs200897117, COSV62464494, COSV62464657; called by muse, mutect2, varscan2
- CD22 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1162769495, COSV50049718; called by muse, mutect2, varscan2
- CD22 | c.2313C>G p.N771K | Missense Mutation (SNP) | VAF 87/547 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV50059244; called by muse, mutect2, varscan2
- CDH5 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs746527849, COSV58518767; called by muse, mutect2, varscan2
- CUBN | c.9371G>A p.S3124N | Missense Mutation (SNP) | VAF 162/525 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV64721543; called by muse, mutect2, varscan2
- DNAH8 | c.2947T>A p.S983T | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100545023; called by muse, mutect2
- DZANK1 | c.629A>G p.K210R (on ENST00000262547 / NM_001099407.1; = p.K11R on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as rs756268579, COSV52754105; called by muse, mutect2, varscan2
- E2F2 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100674868, COSV62276253; called by muse, mutect2, varscan2
- ELK1 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV55953948; called by muse, mutect2, varscan2
- FAM78A | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as COSV99908520; called by muse, mutect2
- FAT4 | c.4286T>C p.I1429T | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67893534; called by muse, mutect2, varscan2
- FBXO38 | c.2653G>C p.E885Q | Missense Mutation (SNP) | VAF 106/119 reads (89%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV57029522; called by muse, mutect2, varscan2
- GOLGA5 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV50834033; called by muse, mutect2, varscan2
- GPATCH4 | c.32-5C>T | Splice Region (SNP) | VAF 50/55 reads (91%) | catalogued as COSV58040822; called by muse, mutect2, varscan2
- GPR119 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV52276169; called by muse, mutect2, varscan2
- GRIN2D | c.1200+1G>C p.X400_splice | Splice Site (SNP) | VAF 20/25 reads (80%) | catalogued as COSV54380775; called by muse, mutect2, varscan2
- GRK7 | c.1055G>C p.G352A | Missense Mutation (SNP) | VAF 372/418 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53824058; called by muse, mutect2, varscan2
- HLA-DRA | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 219/809 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV66622927; called by muse, mutect2, varscan2
- HPS5 | c.3004G>A p.A1002T (on ENST00000349215 / NM_181507.2; = p.A888T on NM_007216.4) | Missense Mutation (SNP) | VAF 144/309 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61687730; called by muse, mutect2, varscan2
- HUWE1 | c.5708C>G p.S1903* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV53355425; called by muse, mutect2, varscan2
- IQGAP2 | c.3923T>C p.I1308T | Missense Mutation (SNP) | VAF 90/97 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV57177284; called by muse, mutect2, varscan2
- KCNA4 | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100069192, COSV60254086; called by muse, mutect2, varscan2
- KRT78 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 216/531 reads (41%) | catalogued as COSV58852273, COSV58852633; called by muse, mutect2, varscan2
- LARP1 | c.2233+1G>T p.X745_splice (on ENST00000518297 / NM_033551.3; = p.X668_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 54/59 reads (92%) | catalogued as COSV60429137; called by muse, mutect2, varscan2
- LRFN5 | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 47/102 reads (46%) | catalogued as rs1471489488, COSV53267083, COSV53274495; called by muse, mutect2, varscan2
- MAGI2 | c.409A>C p.T137P | Missense Mutation (SNP) | VAF 225/549 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62680494; called by muse, mutect2, varscan2
- MAP2 | c.2509G>C p.E837Q | Missense Mutation (SNP) | VAF 249/828 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV52299526; called by muse, mutect2, varscan2
- MGAT5 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 115/254 reads (45%) | catalogued as COSV56098763, COSV99925180; called by muse, mutect2, varscan2
- MPG | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54738977; called by muse, mutect2, varscan2
- NRAP | c.2953A>G p.S985G (on ENST00000359988 / NM_001322945.2; = p.S950G on NM_006175.4) | Missense Mutation (SNP) | VAF 403/427 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63492490; called by muse, mutect2, varscan2
- NUMA1 | c.3823G>A p.E1275K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV61188232; called by muse, mutect2, varscan2
- OR7D4 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 176/633 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV58072079; called by muse, mutect2, varscan2
- PHKA1 | c.1472G>C p.R491T | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV59808504; called by muse, varscan2
- PLCE1 | c.2735A>G p.N912S | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53360943; called by muse, mutect2, varscan2
- POTEF | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV100664867; called by muse, mutect2, varscan2
- PPP1R3A | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs752150752, COSV52887336; called by muse, mutect2, varscan2
- PPP1R9A | c.1612A>G p.T538A | Missense Mutation (SNP) | VAF 28/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99195516; called by muse, mutect2
- PRPF19 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 34/52 reads (65%) | catalogued as COSV57128614; called by muse, mutect2, varscan2
- PRPF39 | c.1811_1813del p.L604_K605delins* | Nonsense Mutation (DEL) | VAF 66/133 reads (50%) | catalogued as COSV53533120; called by mutect2, pindel, varscan2
- PTH2R | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 242/813 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55918063; called by muse, mutect2, varscan2
- RAG1 | c.2906A>C p.K969T | Missense Mutation (SNP) | VAF 294/661 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV55026561; called by muse, mutect2, varscan2
- RASGRF2 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99429135; called by muse, mutect2, varscan2
- RFTN1 | c.1703_1706del p.E568Afs*21 | Frame Shift Del (DEL) | VAF 354/407 reads (87%) | catalogued as COSV61921113; called by mutect2, pindel, varscan2
- SCN3A | c.5303C>G p.A1768G | Missense Mutation (SNP) | VAF 288/1021 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51808405, COSV51816826; called by muse, mutect2, varscan2
- SEMA3A | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 254/480 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV54879550; called by muse, mutect2, varscan2
- SKP2 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 150/376 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99948052; called by muse, mutect2, varscan2
- SLC23A3 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99841098; called by muse, mutect2
- SLC25A23 | c.780C>A p.F260L | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs192489049, COSV51196603; called by muse, mutect2, varscan2
- SLC9A6 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 185/446 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV65788507, COSV65788665; called by muse, mutect2, varscan2
- SLIT1 | c.1157+2T>G p.X386_splice | Splice Site (SNP) | VAF 22/41 reads (54%) | catalogued as COSV56594036; called by muse, mutect2, varscan2
- SNTG2 | c.210T>A p.N70K | Missense Mutation (SNP) | VAF 228/262 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV57995775; called by muse, mutect2
- SPATA31D1 | c.2188G>C p.G730R | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs368257035, COSV61198556; called by muse, mutect2, varscan2
- SUPT3H | c.424A>G p.N142D (on ENST00000371460 / NM_181356.3; = p.N131D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.444); catalogued as COSV60944859; called by muse, mutect2
- TAF1C | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs147204923, COSV58987755; called by muse, mutect2, varscan2
- TCTE1 | c.941T>G p.L314W | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65255942; called by muse, mutect2, varscan2
- TMED3 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55303204; called by muse, mutect2, varscan2
- TP63 | c.319A>T p.M107L | Missense Mutation (SNP) | VAF 196/209 reads (94%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53213594; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV61457358; called by muse, mutect2, varscan2
- TRPC1 | c.2144A>G p.N715S (on ENST00000476941 / NM_001251845.2; = p.N681S on NM_003304.4) | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.931); catalogued as COSV99858688; called by muse, mutect2
- TTLL7 | c.647del p.L216Qfs*26 | Frame Shift Del (DEL) | VAF 79/206 reads (38%) | catalogued as COSV53086528; called by mutect2, pindel, varscan2
- TTN | c.99052T>A p.S33018T (on ENST00000591111; = p.S25594T on NM_003319.4) | Missense Mutation (SNP) | VAF 24/430 reads (6%) | PolyPhen possibly damaging (0.794); catalogued as COSV100611046; called by muse, mutect2
- TTN | c.13808C>T p.T4603M (on ENST00000591111; = p.T3676M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/251 reads (31%) | PolyPhen benign (0.014); catalogued as rs371455094; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TUBB4B | c.1222T>A p.F408I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61118070; called by muse, mutect2, varscan2
- TULP4 | c.1621A>G p.K541E | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65578265; called by muse, mutect2, varscan2
- UBR4 | c.10810G>T p.E3604* | Nonsense Mutation (SNP) | VAF 180/492 reads (37%) | catalogued as COSV100920717; called by muse, mutect2, varscan2
- UBXN2B | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 147/452 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs915645240, COSV68308507, COSV68309413; called by muse, mutect2, varscan2
- USP34 | c.5456A>T p.N1819I | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV68403654; called by muse, mutect2, varscan2
- VPS13B | c.11945C>A p.A3982D | Missense Mutation (SNP) | VAF 118/310 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV52554276; called by muse, mutect2, varscan2
- WDPCP | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 461/1767 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55426100; called by muse, mutect2, varscan2
- WDR49 | c.878C>A p.P293H (on ENST00000308378 / NM_001366158.1; = p.P634H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 281/601 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57712982; called by muse, mutect2, varscan2
- WIPF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs754655046, COSV54210700; called by muse, mutect2, varscan2
- WWC3 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 273/669 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367881383, COSV66501866; called by muse, mutect2, varscan2
- YME1L1 | c.633G>C p.L211F (on ENST00000326799 / NM_139312.3; = p.L154F on NM_014263.4) | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.41); catalogued as COSV58760503, COSV58761143; called by muse, mutect2, varscan2
- ABCC8 | c.3703_3733del p.I1235Dfs*20 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | called by mutect2, pindel
- AL121899.2 | c.1946_1965del p.L649Pfs*5 | Frame Shift Del (DEL) | VAF 47/109 reads (43%) | called by mutect2, pindel, varscan2
- CCDC38 | c.352_353del p.D118Qfs*19 | Frame Shift Del (DEL) | VAF 63/206 reads (31%) | called by pindel, varscan2
- FAT4 | c.7290_7295del p.K2430_D2431del | In Frame Del (DEL) | VAF 129/152 reads (85%) | called by mutect2, pindel, varscan2
- GPR179 | c.5883_5908del p.W1961Cfs*10 (on ENST00000621958; = p.W1960Cfs*10 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 44/55 reads (80%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.12871+5_12871+23del p.X4291_splice | Splice Site (DEL) | VAF 20/44 reads (45%) | called by pindel, varscan2*
- MADD | c.851_854del p.L284Qfs*8 | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- MSN | c.1464_1469del p.E489_A490del | In Frame Del (DEL) | VAF 232/591 reads (39%) | called by mutect2, pindel, varscan2
- PAK5 | c.1816_1832del p.T606Pfs*2 | Frame Shift Del (DEL) | VAF 28/308 reads (9%) | called by mutect2, pindel
- ABCA5 | c.3924A>T p.S1308= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV67017888; called by muse, mutect2, varscan2
- ADGRG3 | c.1248T>C p.S416= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as COSV59651801; called by muse, mutect2, varscan2
- ANK3 | c.1119G>A p.V373= | Silent (SNP) | VAF 215/456 reads (47%) | catalogued as COSV55069592; called by muse, mutect2, varscan2
- ANKRD30A | c.1992A>T p.T664= (on ENST00000611781; = p.T608= on NM_052997.2) | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs780645339, COSV64615578; called by muse, mutect2, varscan2
- ARMCX1 | c.96C>T p.D32= | Silent (SNP) | VAF 81/158 reads (51%) | catalogued as rs782411889, COSV65705361; called by muse, mutect2, varscan2
- CCDC77 | c.1053T>C p.D351= | Silent (SNP) | VAF 66/234 reads (28%) | catalogued as COSV53474223; called by muse, mutect2, varscan2
- CHRAC1 | c.81C>A p.I27= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV55270206; called by muse, mutect2
- ELMO1 | c.363A>T p.I121= | Silent (SNP) | VAF 164/309 reads (53%) | catalogued as COSV60314066; called by muse, mutect2, varscan2
- EP400 | c.3450C>T p.A1150= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs759145972, COSV57779035; called by muse, mutect2, varscan2
- GCLC | c.927A>G p.R309= (on ENST00000643939; = p.R307= on NM_001498.4) | Silent (SNP) | VAF 39/437 reads (9%) | catalogued as COSV57596661; called by muse, mutect2
- GRIN3A | c.2179T>C p.L727= | Silent (SNP) | VAF 217/432 reads (50%) | catalogued as COSV62456181; called by muse, mutect2, varscan2
- JCAD | c.1935G>T p.T645= | Silent (SNP) | VAF 7/202 reads (3%) | catalogued as rs942769637, COSV100948332; called by muse, mutect2
- LRCH2 | c.960A>G p.S320= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV57755214; called by muse, mutect2, varscan2
- MAT2A | c.927T>A p.G309= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99289888; called by muse, mutect2, varscan2
- MAT2A | c.928C>T p.L310= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99289891; called by muse, mutect2, varscan2
- NBPF1 | c.1365A>G p.E455= | Silent (SNP) | VAF 388/2126 reads (18%) | catalogued as rs746296343, COSV55327276; called by muse, varscan2
- NONO | c.279A>C p.L93= | Silent (SNP) | VAF 180/382 reads (47%) | catalogued as COSV52138943; called by muse, mutect2, varscan2
- NUMA1 | c.2955G>T p.R985= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as rs1201452725, COSV61188240; called by muse, mutect2, varscan2
- OR6X1 | c.498C>T p.F166= | Silent (SNP) | VAF 124/245 reads (51%) | catalogued as COSV60010110; called by muse, mutect2, varscan2
- PCDHA2 | c.1233C>T p.S411= | Silent (SNP) | VAF 105/118 reads (89%) | catalogued as rs782096647, COSV65369099; called by muse, mutect2, varscan2
- PKNOX2 | c.1164G>A p.Q388= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV53545654, COSV53550240; called by muse, mutect2, varscan2
- PLD2 | c.39C>T p.D13= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV54007719; called by muse, mutect2, varscan2
- RXRG | c.1260G>T p.L420= | Silent (SNP) | VAF 182/402 reads (45%) | catalogued as rs1166985005, COSV100717509; called by muse, mutect2, varscan2
- SLC39A2 | c.81C>T p.I27= | Silent (SNP) | VAF 103/263 reads (39%) | catalogued as COSV53870516; called by muse, mutect2, varscan2
- UBR4 | c.10809G>A p.V3603= | Silent (SNP) | VAF 181/500 reads (36%) | catalogued as COSV100920718; called by muse, mutect2, varscan2
- USP37 | c.2622G>A p.E874= | Silent (SNP) | VAF 251/627 reads (40%) | catalogued as rs71415835, COSV51445235; called by muse, mutect2, varscan2
- ZBTB4 | c.1917C>T p.D639= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs537131535, COSV60981654; called by muse, mutect2, varscan2
- ZNF112 | c.2484A>G p.T828= (on ENST00000337401 / NM_001083335.2; = p.T822= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 258/297 reads (87%) | catalogued as COSV61621205; called by muse, mutect2, varscan2
- C8orf31 | n.502C>G | RNA (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- LRGUK | c.-1G>C | 5'UTR (SNP) | VAF 140/323 reads (43%) | catalogued as COSV99604171; called by muse, mutect2, varscan2
- RPL7A | c.496-75G>T | Intron (SNP) | VAF 21/25 reads (84%) | catalogued as rs1302559769, COSV100034673; called by muse, mutect2, varscan2
- SLC15A4 | c.*2C>A | 3'UTR (SNP) | VAF 81/188 reads (43%) | catalogued as COSV99903563; called by muse, mutect2, varscan2
- TTN | c.10360+4717del | Intron (DEL) | VAF 142/583 reads (24%) | catalogued as COSV100614525; called by mutect2, pindel, varscan2
- WNK1 | c.2140-2602A>G | Intron (SNP) | VAF 61/296 reads (21%) | catalogued as COSV60039478; called by muse, mutect2, varscan2
